Somatic mutation profile of tumor specimen MP2PRT-PATEMR-TMP1-A (aliquot MP2PRT-PATEMR-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PATEMR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.3 years (3,770 days).
Specimen MP2PRT-PATEMR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce6f5ad4-2c16-4ae1-9986-63731067ba42.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATEMR-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATEMR-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b7ce27d2-1c19-4d51-945b-d3d105dccb02

The open-access MAF lists 23 somatic variants for this specimen: 15 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 7, 5'UTR 1, Splice Site 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DSCAML1 | c.1732G>A p.A578T (on ENST00000321322; = p.A518T on NM_020693.4) | Missense Mutation (SNP) | VAF 74/299 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as rs771272739; called by muse, mutect2, varscan2
- FBN1 | c.2098C>T p.P700S | Missense Mutation (SNP) | VAF 124/299 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs745694291; called by muse, mutect2, varscan2
- HYDIN | c.1949G>A p.R650H | Missense Mutation (SNP) | VAF 93/202 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs746310702; called by muse, mutect2, varscan2
- PAQR9 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 166/407 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.88); catalogued as COSV61419205; called by muse, mutect2, varscan2
- TACR3 | c.1207G>A p.V403M | Missense Mutation (SNP) | VAF 144/342 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as rs553885967, COSV59197525; called by muse, mutect2, varscan2
- ACSS3 | c.1462G>T p.D488Y | Missense Mutation (SNP) | VAF 76/192 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by mutect2, varscan2
- ALMS1 | c.916G>A p.V306I | Missense Mutation (SNP) | VAF 178/409 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- GOLGA8S | c.229-1G>C p.X77_splice | Splice Site (SNP) | VAF 42/156 reads (27%) | called by muse, mutect2
- IGLV4-60 | c.360_362delinsACTCCC | In Frame Ins (INS) | VAF 15/29 reads (52%) | called by pindel, varscan2*
- KCNC3 | c.769C>G p.P257A | Missense Mutation (SNP) | VAF 122/232 reads (53%) | SIFT tolerated (0.84); PolyPhen benign (0.003); called by muse, varscan2
- LTC4S | c.26C>G p.A9G | Missense Mutation (SNP) | VAF 117/277 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- MUC16 | c.22792G>C p.D7598H | Missense Mutation (SNP) | VAF 41/304 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PLEKHH3 | c.2206G>C p.V736L | Missense Mutation (SNP) | VAF 120/271 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SETBP1 | c.4195T>A p.F1399I | Missense Mutation (SNP) | VAF 112/253 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- SEZ6 | c.2368C>T p.P790S | Missense Mutation (SNP) | VAF 86/430 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- CHPF | c.1872C>T p.F624= | Silent (SNP) | VAF 76/418 reads (18%) | called by muse, mutect2, varscan2
- DOCK1 | c.5382C>T p.D1794= | Silent (SNP) | VAF 182/545 reads (33%) | catalogued as rs575066508; called by muse, mutect2, varscan2
- MUC12 | c.3690G>A p.T1230= (on ENST00000379442; = p.T1087= on NM_001164462.1) | Silent (SNP) | VAF 96/1854 reads (5%) | catalogued as rs1283055121; called by muse, mutect2
- NUP107 | c.1449G>A p.L483= | Silent (SNP) | VAF 27/186 reads (15%) | called by muse, mutect2, varscan2
- RNF148 | c.501T>A p.I167= | Silent (SNP) | VAF 182/435 reads (42%) | called by muse, mutect2, varscan2
- SEZ6 | c.2790C>T p.I930= | Silent (SNP) | VAF 57/320 reads (18%) | catalogued as rs1160994298; called by muse, mutect2, varscan2
- SMCHD1 | c.2940C>G p.V980= | Silent (SNP) | VAF 81/211 reads (38%) | catalogued as rs1488080170, COSV55250827, COSV55252490; called by muse, mutect2, varscan2
- REPIN1 | c.-108G>C | 5'UTR (SNP) | VAF 56/313 reads (18%) | called by muse, varscan2
